Gene-level copy-number profile of tumor specimen C3L-10135-01 from CPTAC case C3L-10135, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 64.6 years (23,599 days).
Specimen C3L-10135-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e3f8a1d2-7ffb-4bbd-b20d-59e04f9fa6a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-10135-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/0e2cec04-2dc8-465a-b51b-3ae1ed62e985

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 552; copy number 1: 5,797; copy number 2: 39,775; copy number 3: 10,212; copy number 4: 2,568; copy number 5: 12.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,088,457, 8 genes (within-gene range 0–2): LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2.
- chr3:60,616,822–60,732,636, 5 genes (within-gene range 0–1): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr4:90,838,903–90,839,037, 1 gene (within-gene range 0–1): TMSB4XP8.
- chr9:9,442,060–9,803,784, 2 genes (within-gene range 0–2): RN7SL5P, AL513422.1.
- chr16:78,495,926–78,553,296, 4 genes (within-gene range 0–1): AC046158.1, AC046158.4, AC046158.2, AC046158.3.
- chr17:82,519,713–82,734,143, 12 genes: FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–2): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,289,923–158,357,553, 3 genes, copy number 5: CD1C, CD1B, CD1E.
- chr18:2,916,994–3,013,144, 1 gene, copy number 5 (within-gene range 3–5): LPIN2.
- chr18:2,967,018–3,025,566, 4 genes, copy number 5: AP000919.2, SNRPCP4, AP005431.1, SNORA70.
- chr18:35,581,117–35,717,978, 4 genes, copy number 5: GALNT1, MIR3975, AC090220.1, AC090229.1.

Autosomal genes at a single copy (total copy number 1): 3,457. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
